MMRF case MMRF_2422 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/53618a76-992d-4e73-b5fb-d5f4b43f7662

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.7 years (22,888 days); ISS stage: I; Days to last known disease status: 731 days (2.0 years); Days to last follow up: 731 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 237 days; Days to treatment end: 237 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 254 days; Days to treatment end: 254 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 255 days; Days to treatment end: 255 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -34 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 293 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 5.18 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.1 g/dL; Glucose 4.79 mmol/L; C-Reactive Protein 1.5 mg/dL.
- Day 71 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 5.45 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 4 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 140 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 5.72 mmol/L.
- Day 141 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 7.32 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 3.93 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 6.49 mmol/L.
- Day 254 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 8.08 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 2.43 µg/mL; Lactate Dehydrogenase 9.92 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 3.56 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 4.62 mmol/L.
- Day 325 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 9.43 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 144 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 4.57 mmol/L.
- Day 393 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 8.36 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 229 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.7 g/dL; Glucose 4.62 mmol/L.
- Day 449 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 7.95 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 171 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 48 g/L; Total Protein 6.7 g/dL; Glucose 5.34 mmol/L.
- Day 541 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 7.72 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 157 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 4.84 mmol/L.
- Day 632 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 7.93 g/L; Immunoglobulin A 1.35 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 163 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 5.83 mmol/L.
- Day 731 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 8.17 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -34: Weight: 83 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2422_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -34 days.
- Sample MMRF_2422_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -34 days.
